Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4797, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4797-01A (Primary Tumor).

[page 1 of 3]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Diagnosed case of right renal tumor; upper pole measuring 5.0 x 3.4 cm on CT scan. Rule out RCC of right kidney.

Specimens Submitted:

- 1: Kidney, right; total nephrectomy
- 2: Lymph nodes, paracaval and precaval; excision
- 3: Adrenal gland, right, and supra hilar lymph nodes; resection

DIAGNOSIS:

1. Kidney, right; total nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 4.5 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Not identified

Invasion into muscular branches of renal vein in the renal sinus is identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

2. Lymph nodes, paracaval and precaval; excision:

Lymph Nodes:

Number of nodes examined:5

[page 2 of 3]
[REDACTED]

Number of metastatic nodes:0

3. Adrenal gland, right, and suprahilar lymph nodes; resection:

Benign adrenal gland.

No lymph node tissue identified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	

Gross Description:

[REDACTED]

1).The specimen is received fresh labeled "right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 320 g in total. The kidney measures 11.0 x 5.0 x 3.5 cm. The attached ureter measures 6.5 cm in length and 0.5 cm in diameter. The attached renal vein measures 1.2 cm in length and 0.7 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. The adrenal gland is not present. The kidney is inked green and bivalved to reveal a 4.5 x 3.0 x 2.8 cm infiltrating, soft, variegated tan/ yellow/red tumor mass with extensive hemorrhage, located in the upper pole and extending to the sinus and the renal capsule. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.5 cm and the calyces appear normal. There are no lymph nodes identified in the perinephric fat. A representative section of the tumor was sent for frozen section. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

FSC -- frozen section control

UVM -- ureteral and vessel margins

T-- tumor (tumor with capsule in block 2)

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

[REDACTED]

2). The specimen is received in formalin, labeled "Paracaval and precaval lymph nodes " and consists of multiple pink tan firm lymph nodes ranging from 0.4 to 1.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

BLN-- bisected lymph nodes

[REDACTED]

3).The specimen is received in formalin, labeled "Right adrenal and suprahilar nodes" and consists of an adrenal gland with a moderate amount of attached adipose tissue, with a trimmed weight of 8.5 g. The adrenal gland measures 6.5 x 2.2 x 1.0 cm, with a yellow red cortical medullary junction and, small red-brown hemorrhagic foci in the medulla. No lymph nodes are grossly identified. Representative sections of the adrenal and the surrounding tissue are submitted.

Summary of sections:

[page 3 of 3]
[REDACTED]

A-- adrenal
U -- surrounding tissue

Summary of Sections:

Part 1: Kidney, right; total nephrectomy

Block	Sect. Site	PCs
1	{not entered}	1
1	k	1
1	rp	1
2	t	2
1	thf	1
1	tk	1
2	tsf	2
1	uvm	1

Part 2: Lymph nodes, paracaval and precaval; excision

Block	Sect. Site	PCs
1	bln	1
1	ln	1

Part 3: Adrenal gland, right, and supra hilar lymph nodes; resection

Block	Sect. Site	PCs
2	a	2
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. [REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED]

Source: NCI Genomic Data Commons file f2515287-6fc4-4648-9fe3-1a9232b6afad (TCGA-BP-4797.9BA3733C-115D-44AF-8F4A-28ABB6C73087.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).